Somatic mutation profile of tumor specimen TCGA-43-7656-01A (aliquot TCGA-43-7656-01A-11D-2122-08) from TCGA case TCGA-43-7656, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.2 years (25,991 days).
Specimen TCGA-43-7656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa3667c-83cc-4bf9-9246-5f1ac941a439.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-7656-10A (Blood Derived Normal), aliquot TCGA-43-7656-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86434249-7c93-426e-9a1a-0d5e683f9049

The open-access MAF lists 381 somatic variants for this specimen: 287 protein-altering or splice-affecting, 83 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 83, Nonsense Mutation 19, Splice Site 10, RNA 6, Frame Shift Ins 4, 3'UTR 3, Frame Shift Del 2, Intron 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs794728710, COSV100770814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1472A>G p.Q491R (on ENST00000373993 / NM_138932.2; = p.Q483R on NM_014576.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.444); catalogued as COSV99256562; called by muse, mutect2, varscan2
- ABCA13 | c.3193C>G p.L1065V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV101330076; called by muse, varscan2
- ABCA13 | c.6897G>T p.M2299I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101330077; called by muse, mutect2, varscan2
- ABCA4 | c.6124G>A p.V2042I | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs138384263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG8 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99699883; called by muse, mutect2
- AC092143.1 | c.1897G>C p.V633L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100205656, COSV100205888, COSV59248993; called by muse, mutect2, varscan2
- ACAD11 | c.99G>C p.L33F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1559984641, COSV99392139; called by muse, mutect2, varscan2
- ACSL6 | c.2036C>A p.P679H (on ENST00000379240; = p.P704H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99733872; called by muse, mutect2, varscan2
- ADGRF2 | c.286A>G p.K96E (on ENST00000296862 / NM_001368115.2; = p.K28E on NM_153839.7) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV99731317; called by muse, mutect2, varscan2
- ADGRF4 | c.1883G>C p.G628A | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV51950927, COSV99348488; called by muse, mutect2, varscan2
- AEN | c.846G>C p.W282C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as COSV100237474; called by muse, mutect2, varscan2
- AKAP13 | c.4829C>T p.A1610V (on ENST00000394518 / NM_007200.5; = p.A1614V on NM_006738.6) | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100773922; called by muse, mutect2, varscan2
- AKR1B1 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99605278; called by muse, mutect2, varscan2
- ALDH16A1 | c.1085G>A p.S362N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as COSV99512972; called by muse, mutect2, varscan2
- ANKRD22 | c.22-1G>A p.X8_splice | Splice Site (SNP) | VAF 83/328 reads (25%) | catalogued as COSV100905479; called by muse, mutect2, varscan2
- ANO1 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as COSV100304115, COSV60283250; called by muse, mutect2, varscan2
- APOB | c.11675C>T p.P3892L | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266017; called by muse, mutect2, varscan2
- ARAP1 | c.3954G>T p.R1318= (on ENST00000393609 / NM_001040118.2; = p.R1073= on NM_015242.4) | Splice Region (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100501967; called by muse, mutect2, varscan2
- ARAP3 | c.2801-1G>T p.X934_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | catalogued as COSV53348866, COSV99499806; called by muse, mutect2, varscan2
- ARHGEF40 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.234); catalogued as COSV100070410; called by muse, mutect2, varscan2
- ARSJ | c.651G>C p.M217I | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100192782; called by muse, mutect2, varscan2
- ASMT | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101172476; called by muse, mutect2, varscan2
- ASTN1 | c.2405G>C p.G802A | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99922003; called by muse, mutect2, varscan2
- ATP6V1C2 | c.257T>G p.V86G | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV99695843; called by muse, mutect2
- B3GAT3 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs749411703, COSV99605960; called by muse, mutect2, varscan2
- BCO2 | c.1078A>C p.N360H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100730370; called by muse, mutect2, varscan2
- BFSP1 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100925376, COSV64899487; called by muse, mutect2, varscan2
- BOD1L1 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs745427942, COSV50007335, COSV99239553; called by muse, mutect2, varscan2
- BPNT2 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389084; called by muse, mutect2, varscan2
- BSN | c.6242G>A p.G2081D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV99608728; called by muse, mutect2, varscan2
- CCDC148 | c.521T>A p.F174Y | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99320594; called by muse, mutect2, varscan2
- CD209 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.706); catalogued as COSV52652694; called by muse, varscan2
- CDK19 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100098672; called by muse, mutect2, varscan2
- CEP170 | c.4156G>T p.D1386Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100317213; called by mutect2, varscan2
- CFAP65 | c.1570C>A p.R524S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as COSV99838357; called by muse, mutect2, varscan2
- CHIT1 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.55); catalogued as COSV99705340; called by muse, mutect2, varscan2
- CLVS2 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.372); catalogued as rs777116578, COSV99252959; called by muse, mutect2, varscan2
- CNTNAP5 | c.3852C>G p.D1284E | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101443662, COSV70521008; called by muse, mutect2
- COG7 | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV100207601; called by muse, mutect2, varscan2
- COL1A2 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV51961311; called by muse, mutect2, varscan2
- COL22A1 | c.2683G>T p.G895* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100278808, COSV57329768; called by muse, mutect2, varscan2
- COL22A1 | c.2682G>C p.Q894H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV100278810; called by muse, mutect2, varscan2
- COL4A3 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101170321; called by muse, mutect2, varscan2
- COL6A6 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as COSV100650334; called by muse, mutect2, varscan2
- COL9A1 | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV100611526; called by muse, mutect2, varscan2
- CPA4 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV99745074; called by muse, mutect2, varscan2
- CPS1 | c.4206T>A p.N1402K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99243191; called by muse, mutect2
- CTAGE15 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101372157; called by muse, mutect2, varscan2
- CWH43 | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99893527; called by muse, mutect2, varscan2
- CYP11A1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs531719978, COSV51430661; called by muse, mutect2, varscan2
- CYP2W1 | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1436961885, COSV100417207; called by muse, mutect2, varscan2
- DCAF8L1 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.156); catalogued as COSV101491473, COSV104437503; called by muse, mutect2
- DEFB112 | c.131A>C p.N44T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.234); catalogued as COSV100452155; called by muse, mutect2, varscan2
- DEPDC5 | c.3304C>G p.P1102A (on ENST00000400246; = p.P1171A on NM_014662.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.484); catalogued as COSV99835629; called by muse, mutect2
- DHRS9 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV100513531; called by muse, mutect2, varscan2
- DIS3L2 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV99806453; called by muse, mutect2, varscan2
- DIXDC1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555172373, COSV100180277; called by muse, mutect2
- DLGAP2 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as rs762248808, COSV101420968; called by muse, mutect2, varscan2
- DNAH10 | c.1418T>G p.F473C (on ENST00000409039; = p.F412C on NM_207437.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV101292319; called by muse, mutect2, varscan2
- DNAH5 | c.12227G>C p.G4076A | Missense Mutation (SNP) | VAF 91/160 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450542; called by muse, mutect2, varscan2
- DNAH7 | c.5311C>A p.P1771T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100415582; called by muse, mutect2, varscan2
- DNAH9 | c.1902-2A>G p.X634_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99306245; called by muse, mutect2, varscan2
- DNAJC21 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs757180547, COSV57759491; called by muse, mutect2, varscan2
- DOK5 | c.171T>A p.H57Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.967); catalogued as COSV99374076; called by muse, varscan2
- DPP6 | c.1169C>G p.T390S (on ENST00000377770 / NM_001364500.2; = p.T328S on NM_001936.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.803); catalogued as COSV100125981; called by muse, mutect2, varscan2
- DSG1 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936101; called by muse, mutect2, varscan2
- DSG3 | c.1025G>T p.S342I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV99934280; called by muse, mutect2, varscan2
- DST | c.10598G>T p.S3533I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99757079; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99709182; called by muse, mutect2, varscan2
- DYNC1LI2 | c.339G>T p.L113F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.949); catalogued as COSV99263057; called by muse, mutect2, varscan2
- DYSF | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV99247763; called by muse, mutect2, varscan2
- DZIP3 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1179282160, COSV100847843; called by muse, mutect2, varscan2
- E2F8 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.657); catalogued as rs754334957, COSV100001551, COSV51463335; called by muse, mutect2, varscan2
- EBF3 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100799287, COSV62482780; called by muse, mutect2, varscan2
- EDNRB | c.773C>T p.P258L (on ENST00000377211 / NM_001201397.1; = p.P168L on NM_000115.5) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.493); catalogued as COSV100526735; called by muse, mutect2, varscan2
- EDNRB | c.772C>A p.P258T (on ENST00000377211 / NM_001201397.1; = p.P168T on NM_000115.5) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as COSV100526736; called by muse, mutect2, varscan2
- EPHA5 | c.1857-1G>T p.X619_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV56642407, COSV56668135; called by muse, mutect2, varscan2
- EPHB1 | c.386G>T p.W129L | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV101213243; called by muse, mutect2, varscan2
- EPS8L1 | c.2044C>A p.R682S (on ENST00000201647 / NM_133180.3; = p.R555S on NM_017729.3) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs750103854, COSV99136466; called by muse, mutect2, varscan2
- FAM135B | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99424589; called by muse, mutect2, varscan2
- FAM187B | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV100220011; called by muse, mutect2, varscan2
- FAM71B | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57230186; called by muse, mutect2, varscan2
- FECH | c.975G>T p.R325S | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as COSV100023627; called by muse, mutect2, varscan2
- FGGY | c.1534A>T p.K512* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100364992; called by muse, mutect2, varscan2
- FKBP7 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV99247612; called by muse, mutect2, varscan2
- FLI1 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); catalogued as rs764743895, COSV55642567; called by muse, mutect2, varscan2
- FLNC | c.5399-1G>A p.X1800_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100368226; called by muse, mutect2
- FOSL2 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99268383; called by muse, mutect2, varscan2
- FOXD4L5 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs1346625015; called by mutect2, varscan2
- FRAS1 | c.10111A>G p.I3371V | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs376048305; called by muse, mutect2, varscan2
- FREM2 | c.1822G>T p.G608W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99749113; called by muse, mutect2, varscan2
- GAB4 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68753286; called by muse, mutect2
- GFRA1 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV100815766; called by muse, varscan2
- GLI3 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as COSV101229907; called by muse, mutect2, varscan2
- GLT6D1 | c.714T>A p.N238K | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100874543; called by muse, mutect2, varscan2
- GNL2 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.521); catalogued as COSV100895009; called by muse, mutect2, varscan2
- GRM1 | c.1460C>A p.T487N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV99266617; called by muse, mutect2, varscan2
- GYG2 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100089051; called by muse, mutect2, varscan2
- HADH | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100531186, COSV100531385; called by muse, mutect2, varscan2
- HMCES | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770080789, COSV101077327; called by muse, mutect2, varscan2
- HOXD3 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV99980215; called by muse, mutect2, varscan2
- HSD17B2 | c.58T>C p.C20R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs981688956, COSV99556644; called by muse, mutect2, varscan2
- IDO2 | c.788A>G p.Y263C (on ENST00000389060; = p.Y276C on NM_194294.2) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV100584787; called by muse, mutect2, varscan2
- INPP5D | c.1868A>G p.E623G (on ENST00000445964 / NM_001017915.3; = p.E622G on NM_005541.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100856831; called by muse, mutect2, varscan2
- INSYN1 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV101138674, COSV101138793; called by muse, mutect2, varscan2
- ITPRID1 | c.1745G>T p.R582M | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100086582; called by muse, mutect2, varscan2
- JPH2 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100881745; called by muse, mutect2, varscan2
- KALRN | c.6271G>T p.V2091L (on ENST00000360013 / NM_001024660.4; = p.V394L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.966); catalogued as COSV99362248; called by muse, mutect2, varscan2
- KALRN | c.6549G>C p.E2183D (on ENST00000360013 / NM_001024660.4; = p.E486D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.245); catalogued as COSV99362249; called by muse, mutect2, varscan2
- KATNIP | c.4073C>A p.A1358D | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99851299; called by muse, mutect2, varscan2
- KCNH5 | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100526800; called by muse, mutect2, varscan2
- KCNJ3 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99715928; called by muse, mutect2, varscan2
- KCNK5 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs886586058, COSV100851869; called by muse, mutect2, varscan2
- KDM5D | c.1571G>A p.W524* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100522244; called by muse, mutect2, varscan2
- KHDRBS1 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100306218; called by muse, mutect2, varscan2
- KIF17 | c.2236C>A p.Q746K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV99929208; called by muse, mutect2, varscan2
- KIF21A | c.3929C>T p.S1310F (on ENST00000361418 / NM_001378440.1; = p.S1297F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.943); catalogued as rs201618273, COSV100735488; called by muse, mutect2, varscan2
- KIFC1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100997104; called by muse, mutect2
- KIR3DL3 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.645); catalogued as COSV99399955; called by muse, mutect2, varscan2
- KMT2C | c.2341G>T p.V781L | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100072659, COSV100073326; called by muse, mutect2
- KNTC1 | c.2398G>T p.V800L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100338414; called by muse, mutect2
- KPNA3 | c.1424A>C p.K475T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99904175; called by muse, mutect2, varscan2
- LAIR1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV100479672; called by muse, mutect2, varscan2
- LCT | c.3091G>A p.G1031R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51554971; called by muse, mutect2, varscan2
- LHX8 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99633879; called by muse, mutect2, varscan2
- LIN7A | c.201+1G>A p.X67_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99692237; called by muse, mutect2, varscan2
- LMAN2L | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV99383424, COSV99383732; called by muse, mutect2, varscan2
- LOXL2 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101207917; called by muse, mutect2, varscan2
- LRFN1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99953011; called by muse, mutect2, varscan2
- LRFN5 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53246439; called by muse, mutect2, varscan2
- LRFN5 | c.1577del p.G526Efs*4 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | catalogued as COSV53272265; called by mutect2, pindel, varscan2
- LRP1 | c.6350A>T p.N2117I | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54516766, COSV99676134; called by muse, mutect2, varscan2
- LRP1B | c.8669C>A p.S2890* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101257742; called by muse, varscan2
- LSAMP | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100370937; called by muse, mutect2, varscan2
- MAG | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs778697016, COSV62701762; called by muse, mutect2, varscan2
- MAGEB6 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV100983763; called by muse, mutect2, varscan2
- MAGEL2 | c.2743G>C p.E915Q | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as COSV100045980; called by muse, mutect2, varscan2
- MAP2 | c.4003G>T p.E1335* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99560354; called by muse, mutect2, varscan2
- MAP3K19 | c.3164C>G p.S1055C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.416); catalogued as COSV100208685; called by muse, mutect2, varscan2
- MAP9 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100250922; called by muse, mutect2, varscan2
- MATK | c.928-2A>G p.X310_splice (on ENST00000310132 / NM_139355.3; = p.X311_splice on NM_002378.4) | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as rs766240755, COSV100036132; called by muse, mutect2, varscan2
- MB21D2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV101164866; called by muse, mutect2, varscan2
- MBP | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as rs748030999, COSV100592711; called by muse, mutect2, varscan2
- MCM10 | c.522T>A p.F174L (on ENST00000484800 / NM_182751.3; = p.F173L on NM_018518.5) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV101098175; called by muse, mutect2, varscan2
- MDH1B | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV100982207; called by muse, mutect2, varscan2
- MID2 | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99464831, COSV99465098; called by muse, mutect2
- MKI67 | c.9597C>G p.C3199W | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV100896640; called by muse, mutect2
- MMADHC | c.685T>A p.S229T | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.721); catalogued as COSV100307216; called by muse, mutect2, varscan2
- MOGAT1 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101490098, COSV71479806; called by muse, mutect2, varscan2
- MS4A14 | c.1179C>A p.H393Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100280497, COSV55733354; called by muse, mutect2, varscan2
- MTRR | c.1325G>T p.R442L (on ENST00000264668; = p.R415L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs748202026, COSV99241799; called by muse, mutect2, varscan2
- MUC4 | c.653C>G p.T218S | Missense Mutation (SNP) | VAF 75/439 reads (17%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.301); catalogued as COSV100640696; called by muse, mutect2, varscan2
- MYH6 | c.1793A>G p.N598S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV100676665; called by muse, mutect2, varscan2
- MYLK3 | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs774586080, COSV101189128; called by muse, mutect2, varscan2
- NDN | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV100086473; called by muse, mutect2, varscan2
- NID2 | c.2896C>A p.Q966K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99356674; called by muse, mutect2, varscan2
- NLGN2 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100259307, COSV100259452; called by muse, mutect2, varscan2
- NLGN4X | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52026313, COSV99322183; called by muse, mutect2, varscan2
- NLRP5 | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV101173724; called by muse, mutect2, varscan2
- NR2C2 | c.1057C>G p.P353A (on ENST00000393102; = p.P372A on NM_003298.5) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100038603; called by muse, mutect2
- NRAP | c.3592C>A p.L1198I (on ENST00000359988 / NM_001322945.2; = p.L1163I on NM_006175.4) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.821); catalogued as COSV100748461; called by muse, mutect2, varscan2
- NRDC | c.764G>T p.R255M | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100703469; called by muse, mutect2, varscan2
- NRXN2 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV99634558; called by muse, mutect2, varscan2
- NRXN2 | c.2187G>T p.E729D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.134); catalogued as COSV99634563; called by muse, mutect2, varscan2
- NRXN3 | c.1660+1G>C p.X554_splice (on ENST00000335750 / NM_001330195.2; = p.X181_splice on NM_004796.6) | Splice Site (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100204534; called by muse, mutect2, varscan2
- NTS | c.336C>A p.H112Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99755042; called by muse, mutect2, varscan2
- NUP210 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99596342; called by muse, mutect2, varscan2
- NUP62 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100352124; called by muse, varscan2
- NYAP1 | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55722249; called by muse, mutect2, varscan2
- OR10V1 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV100275972; called by muse, mutect2, varscan2
- OR4A16 | c.193T>G p.S65A | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV100125265; called by muse, mutect2, varscan2
- OR4M1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100271257; called by muse, mutect2, varscan2
- OR52E6 | c.84G>C p.W28C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100259367, COSV61432580; called by muse, mutect2, varscan2
- OR56A1 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100360488; called by muse, mutect2, varscan2
- OR5A2 | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119764; called by muse, mutect2, varscan2
- OR5T2 | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV100506957, COSV57589256; called by muse, mutect2, varscan2
- OR6K6 | c.40A>T p.R14W | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100933749; called by muse, mutect2, varscan2
- OR6Y1 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100225399; called by muse, mutect2, varscan2
- PANX2 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99348386; called by muse, mutect2
- PAPOLB | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.341); catalogued as COSV101271455; called by muse, mutect2, varscan2
- PCDH11X | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012222; called by muse, mutect2, varscan2
- PCDH11X | c.2241C>A p.H747Q | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100012224; called by muse, mutect2, varscan2
- PCDH11Y | c.2665C>G p.P889A (on ENST00000400457 / NM_032973.2; = p.P878A on NM_032971.3) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99291648, COSV99291958; called by muse, mutect2, varscan2
- PCDH15 | c.3050C>A p.S1017Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs749456118, COSV100221906; called by muse, mutect2, varscan2
- PCDH15 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.358); catalogued as COSV100221908; called by muse, mutect2, varscan2
- PCDHA7 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs782612363, COSV100971531, COSV65348126; called by muse, mutect2, varscan2
- PCDHB10 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs782384506, COSV99504108; called by muse, mutect2, varscan2
- PCLO | c.11842C>A p.P3948T | Missense Mutation (SNP) | VAF 110/384 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV100433447, COSV61655560; called by muse, mutect2, varscan2
- PCLO | c.11000C>T p.A3667V | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100433449, COSV61677457; called by muse, mutect2, varscan2
- PDE1B | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV99226404; called by muse, mutect2, varscan2
- PKHD1 | c.3094A>T p.I1032F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV100583372; called by muse, mutect2, varscan2
- PLCH1 | c.84G>T p.M28I (on ENST00000340059 / NM_001130960.2; = p.M40I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100397114, COSV100398559; called by muse, mutect2, varscan2
- PLEKHG2 | c.4127C>T p.A1376V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV99217575; called by muse, mutect2, varscan2
- PNISR | c.1751G>T p.S584I | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); catalogued as COSV100984380; called by muse, mutect2, varscan2
- POLE | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267025; called by muse, mutect2, varscan2
- PRB4 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 114/747 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV99686605; called by muse, varscan2
- PRF1 | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942628; called by muse, mutect2, varscan2
- PRMT1 | c.32T>C p.M11T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV99881140; called by muse, mutect2, varscan2
- PSMB4 | c.263T>G p.M88R | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as COSV99305061; called by muse, mutect2, varscan2
- PTGDR | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.726); catalogued as COSV100035610; called by muse, mutect2, varscan2
- PTPRH | c.3159G>T p.R1053S | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV54750208, COSV99671090; called by muse, mutect2, varscan2
- PTPRH | c.3158G>T p.R1053M | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV54747212, COSV99670928, COSV99671091; called by muse, mutect2, varscan2
- RALGAPB | c.848G>A p.W283* | Nonsense Mutation (SNP) | VAF 57/195 reads (29%) | catalogued as COSV99485346; called by muse, mutect2, varscan2
- RAP2B | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV100058970; called by muse, mutect2, varscan2
- RBM33 | c.2126G>C p.R709P | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV100265524, COSV56629068; called by muse, mutect2, varscan2
- RIMS1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV53451570; called by muse, mutect2
- RRAS2 | c.409-1G>T p.X137_splice | Splice Site (SNP) | VAF 32/130 reads (25%) | catalogued as COSV99819059; called by muse, mutect2, varscan2
- RYR1 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs142548565, CM157084, COSV100615557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.3934C>A p.Q1312K | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101212939; called by muse, mutect2, varscan2
- SACS | c.9508C>G p.R3170G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.247); catalogued as CM130585, COSV101207489; called by muse, mutect2, varscan2
- SACS | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101207490; called by muse, mutect2, varscan2
- SCN1A | c.1963G>C p.G655R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100320752; called by muse, mutect2, varscan2
- SDHC | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100713692; called by muse, mutect2, varscan2
- SEC24D | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99755994; called by mutect2, varscan2
- SETX | c.6004C>T p.R2002C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99810004; called by muse, mutect2, varscan2
- SH3TC2 | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100101814, COSV60461834; called by muse, mutect2, varscan2
- SHC3 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101011959; called by muse, mutect2, varscan2
- SLC12A5 | c.1552A>G p.T518A (on ENST00000454036 / NM_001134771.2; = p.T495A on NM_020708.5) | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV99716210; called by muse, mutect2, varscan2
- SLC12A7 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.562); catalogued as COSV99370045; called by muse, mutect2, varscan2
- SLC12A9 | c.1958G>A p.S653N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV99307897; called by muse, mutect2, varscan2
- SLC18A1 | c.1445C>A p.P482Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99368642; called by muse, mutect2, varscan2
- SLC18B1 | c.537A>G p.I179M | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV99259147; called by muse, mutect2, varscan2
- SLC39A3 | c.249C>G p.D83E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV99514221; called by muse, mutect2, varscan2
- SLC5A11 | c.208-2A>T p.X70_splice | Splice Site (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100762818; called by muse, mutect2, varscan2
- SLC6A12 | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV100675130, COSV62885768; called by muse, mutect2, varscan2
- SLCO4C1 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV100195144; called by muse, mutect2, varscan2
- SMC1A | c.2791C>G p.Q931E | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.268); catalogued as COSV100447450; called by muse, mutect2, varscan2
- SNAP91 | c.1288G>C p.V430L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99535455; called by muse, mutect2, varscan2
- SORCS1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs769049738, COSV99547251; called by muse, mutect2, varscan2
- SPACA1 | c.715T>A p.F239I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV99389552; called by muse, mutect2, varscan2
- SPAG17 | c.5882C>T p.P1961L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100309342; called by muse, mutect2, varscan2
- SPATA4 | c.375A>T p.L125F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV99709004; called by muse, mutect2, varscan2
- SPG7 | c.1210G>T p.D404Y (on ENST00000268704; = p.D411Y on NM_003119.4) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM164820, COSV99245004; called by muse, mutect2, varscan2
- SPIRE2 | c.1439G>A p.W480* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100988852; called by muse, mutect2
- STYXL2 | c.1521G>T p.R507S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54802738, COSV99609369; called by muse, mutect2, varscan2
- SULT1C2 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs367558634; called by muse, mutect2, varscan2
- SYNE1 | c.25630C>A p.L8544M (on ENST00000367255 / NM_182961.4; = p.L8496M on NM_033071.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV99567082; called by muse, mutect2, varscan2
- SYNE1 | c.25070G>A p.R8357H (on ENST00000367255 / NM_182961.4; = p.R8309H on NM_033071.3) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs766534980, COSV99567087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1C | c.1730C>G p.S577* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100499634; called by muse, mutect2, varscan2
- TANC2 | c.333C>A p.Y111* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV101267478; called by muse, mutect2, varscan2
- TEX44 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as COSV100009772; called by muse, mutect2, varscan2
- TFG | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99561065; called by muse, mutect2, varscan2
- THSD7A | c.3574G>T p.D1192Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV101439756; called by muse, mutect2, varscan2
- TKTL2 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761458; called by muse, mutect2, varscan2
- TM6SF2 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101231609; called by muse, mutect2, varscan2
- TMC8 | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV100531304; called by muse, mutect2, varscan2
- TMEM202 | c.646A>C p.T216P | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100499181; called by muse, mutect2, varscan2
- TNNT1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as COSV99402898; called by muse, mutect2, varscan2
- TOGARAM2 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV101091173; called by muse, mutect2, varscan2
- TPRG1 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100800497; called by muse, mutect2, varscan2
- TRIP12 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1159346137, COSV99390421; called by muse, mutect2, varscan2
- TRPM4 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.61); catalogued as rs770211728, COSV53268474; called by muse, mutect2, varscan2
- TRRAP | c.8403A>T p.K2801N (on ENST00000359863 / NM_001244580.1; = p.K2783N on NM_003496.3) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100722577; called by muse, mutect2, varscan2
- TSHZ2 | c.601A>C p.S201R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100296214; called by muse, mutect2, varscan2
- TTN | c.92423C>A p.P30808H (on ENST00000591111; = p.P23384H on NM_003319.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen probably damaging (0.935); catalogued as COSV100616673; called by muse, mutect2, varscan2
- TTN | c.7936C>A p.P2646T (on ENST00000591111; = p.P2600T on NM_003319.4) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | PolyPhen probably damaging (0.951); catalogued as COSV100616675, COSV60258500; called by muse, mutect2, varscan2
- TUBA1C | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs759689411, COSV99988825; called by muse, mutect2, varscan2
- UGT1A8 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as rs755504518, COSV65080153; called by muse, mutect2, varscan2
- UNC5D | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54776684; called by muse, mutect2, varscan2
- UNC5D | c.2329C>A p.R777S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV99775965; called by muse, mutect2, varscan2
- USP2 | c.1651G>T p.G551* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV52729328, COSV99489720; called by muse, mutect2, varscan2
- VPS13B | c.4064T>C p.L1355P | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1457829606, COSV100662256; called by muse, mutect2, varscan2
- VPS13C | c.9268T>G p.S3090A (on ENST00000644861 / NM_020821.3; = p.S3047A on NM_017684.5) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV99828760; called by muse, mutect2, varscan2
- WDR81 | c.3346G>C p.E1116Q (on ENST00000409644 / NM_001163809.2; = p.E65Q on NM_152348.4) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100488964; called by muse, mutect2, varscan2
- WNT3A | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as COSV99469606, COSV99470314; called by muse, mutect2, varscan2
- WSCD2 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99774724; called by muse, mutect2, varscan2
- XIRP2 | c.1767G>T p.K589N (on ENST00000628543; = p.K764N on NM_152381.6) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99743683; called by muse, mutect2, varscan2
- XRCC5 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV101079640; called by muse, mutect2, varscan2
- ZBED4 | c.3377dup p.S1127Kfs*14 | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | catalogued as rs764637852; called by mutect2, pindel, varscan2
- ZEB1 | c.2159T>A p.L720* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100314518; called by muse, mutect2, varscan2
- ZFHX3 | c.6557A>T p.Q2186L | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV99213216; called by muse, mutect2, varscan2
- ZFHX3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs772845316, COSV51712345; called by muse, mutect2, varscan2
- ZNF184 | c.2249G>A p.G750D | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99279719; called by muse, mutect2, varscan2
- ZNF254 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 128/199 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1173185747, COSV100298222; called by muse, mutect2, varscan2
- ZNF254 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100741655; called by muse, mutect2, varscan2
- ZNF28 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 90/342 reads (26%) | catalogued as COSV100354526; called by muse, mutect2, varscan2
- ZNF385B | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs370937646, COSV100416069; called by muse, mutect2, varscan2
- ZNF420 | c.1580G>C p.G527A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100421390; called by muse, mutect2, varscan2
- ZNF518B | c.1973A>G p.K658R | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV100456743; called by muse, mutect2, varscan2
- ZNF99 | c.1859C>G p.P620R | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101233846; called by muse, mutect2, varscan2
- EPO | c.352dup p.L118Pfs*7 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- HIPK3 | c.1191del p.L398Sfs*26 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | called by mutect2, pindel, varscan2
- IGKV6-21 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO8 | c.1825_1826dup p.M609Ifs*12 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- OR2T2 | c.453dup p.G152Wfs*20 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- ANK2 | c.18A>G p.A6= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100002014; called by muse, mutect2, varscan2
- ARHGEF15 | c.142C>A p.R48= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV100730058, COSV62725867; called by muse, mutect2, varscan2
- ASPH | c.777C>G p.V259= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs760719359, COSV100727608; called by muse, mutect2, varscan2
- ASTN2 | c.558C>T p.A186= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs764482726, COSV100528167; called by muse, mutect2, varscan2
- ASXL3 | c.1704T>C p.S568= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99325190; called by muse, mutect2
- BACE1 | c.552T>C p.Y184= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs1381358337, COSV100475131; called by muse, mutect2, varscan2
- BSN | c.6243C>G p.G2081= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99608731; called by muse, mutect2, varscan2
- CABP1 | c.744G>T p.R248= (on ENST00000316803 / NM_001033677.1; = p.R45= on NM_004276.5) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99974705; called by muse, mutect2, varscan2
- CAMK2B | c.1167C>T p.D389= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs201188394; called by muse, mutect2, varscan2
- CCDC189 | c.898C>A p.R300= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs182267845; called by muse, mutect2, varscan2
- CD40 | c.378G>T p.S126= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs150312341, COSV64848388; called by muse, mutect2, varscan2
- CDH24 | c.1353T>A p.A451= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99943901; called by muse, mutect2, varscan2
- CHRD | c.858C>A p.I286= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as COSV99200477; called by muse, mutect2, varscan2
- CNTNAP2 | c.1260C>T p.G420= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100667050; called by muse, mutect2, varscan2
- COL6A5 | c.7203C>A p.T2401= (on ENST00000312481; = p.T2397= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99593441; called by muse, mutect2, varscan2
- CST4 | c.189C>T p.Y63= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs766999486, COSV54150002, COSV99463266; called by muse, mutect2, varscan2
- CXCL9 | c.222T>C p.C74= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV99345763; called by muse, mutect2, varscan2
- DPPA4 | c.300G>T p.R100= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV100169475; called by muse, mutect2, varscan2
- DYNC2I1 | c.1992C>T p.P664= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs368787425; called by muse, mutect2, varscan2
- EFCAB13 | c.681G>A p.K227= | Silent (SNP) | VAF 105/190 reads (55%) | catalogued as rs1358165580, COSV100516620; called by muse, mutect2, varscan2
- EIF4A2 | c.672G>A p.V224= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV99961244; called by muse, mutect2, varscan2
- EPHB1 | c.1797T>C p.T599= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as COSV101213244; called by muse, mutect2, varscan2
- EPHB4 | c.1260C>G p.V420= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV100639522; called by muse, mutect2, varscan2
- F5 | c.3717C>A p.T1239= | Silent (SNP) | VAF 116/396 reads (29%) | catalogued as COSV100889131; called by muse, mutect2, varscan2
- FAT4 | c.7845G>A p.Q2615= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1262979373, COSV100628848; called by muse, mutect2, varscan2
- FKBP10 | c.1482G>C p.L494= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV99505220; called by muse, mutect2, varscan2
- FPGT | c.492C>T p.Y164= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100907261; called by muse, mutect2, varscan2
- GCN1 | c.873C>T p.D291= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100325407; called by muse, mutect2, varscan2
- GPR158 | c.2730G>A p.K910= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs201167926, COSV66272833; called by muse, mutect2, varscan2
- GRIK3 | c.1407G>T p.L469= | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as COSV100902112; called by muse, mutect2, varscan2
- HOXA1 | c.594A>G p.T198= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV99761252; called by muse, mutect2, varscan2
- HRNR | c.996T>A p.S332= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV100913559; called by muse, mutect2, varscan2
- HSPA1L | c.333G>A p.G111= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV100989404; called by muse, mutect2, varscan2
- IKZF1 | c.1530G>T p.T510= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100498463; called by muse, mutect2, varscan2
- INCENP | c.579C>T p.P193= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99611143; called by muse, mutect2, varscan2
- ITIH6 | c.3027G>C p.L1009= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs752258597, COSV54488534, COSV99513417; called by muse, mutect2, varscan2
- KBTBD3 | c.192G>C p.P64= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101595692, COSV73241582; called by muse, mutect2, varscan2
- KHDC3L | c.174G>C p.R58= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100951111; called by muse, mutect2, varscan2
- KIF16B | c.1036C>T p.L346= | Silent (SNP) | VAF 96/199 reads (48%) | catalogued as COSV100734430; called by muse, mutect2, varscan2
- KLHL1 | c.1314A>G p.L438= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100917436; called by muse, mutect2, varscan2
- KLHL14 | c.1884A>G p.K628= | Silent (SNP) | VAF 71/155 reads (46%) | catalogued as COSV100839222; called by muse, mutect2, varscan2
- KRTAP5-11 | c.174C>T p.G58= | Silent (SNP) | VAF 73/271 reads (27%) | catalogued as rs1406979934, COSV100651827; called by muse, mutect2, varscan2
- LUZP2 | c.783T>G p.S261= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100420085; called by muse, varscan2
- MAGEB3 | c.423C>A p.V141= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV100854711, COSV64397349; called by muse, mutect2, varscan2
- MINDY1 | c.648C>G p.G216= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100385445; called by muse, mutect2, varscan2
- MORC1 | c.2385T>A p.S795= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV99226407; called by muse, mutect2, varscan2
- MYH2 | c.1242C>A p.V414= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as COSV99820312; called by muse, mutect2, varscan2
- MYO15A | c.3348G>A p.V1116= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV99233156; called by muse, mutect2, varscan2
- NLRC4 | c.1365C>G p.L455= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs755592774, COSV61595444; called by muse, mutect2, varscan2
- NXPH2 | c.439C>A p.R147= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99740778, COSV99741052; called by muse, mutect2, varscan2
- ODF2 | c.696C>T p.I232= (on ENST00000434106 / NM_153433.2; = p.I208= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs772121203, COSV100654677; called by muse, mutect2, varscan2
- OR14A16 | c.222C>A p.V74= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100713791, COSV62927061; called by muse, mutect2, varscan2
- OR2W3 | c.174C>A p.P58= | Silent (SNP) | VAF 59/320 reads (18%) | catalogued as COSV100831713; called by muse, mutect2, varscan2
- OR4E2 | c.723G>T p.S241= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100330111, COSV57731842; called by muse, mutect2, varscan2
- OR51B6 | c.198T>A p.A66= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV100971399; called by muse, mutect2, varscan2
- OR5B21 | c.853T>C p.L285= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as COSV100835155; called by muse, mutect2, varscan2
- OR8B8 | c.627G>T p.V209= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs923504981, COSV60144128, COSV60145539; called by muse, mutect2, varscan2
- PLCL1 | c.486C>A p.A162= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV101407029; called by muse, mutect2, varscan2
- PNLIPRP1 | c.579G>A p.L193= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1554864152, COSV100724417; called by muse, mutect2, varscan2
- PPA1 | c.534G>A p.L178= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV100949920; called by muse, mutect2, varscan2
- PRDM15 | c.2940G>T p.L980= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as COSV99520242; called by muse, mutect2, varscan2
- PRKN | c.210G>T p.V70= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100629611; called by muse, mutect2, varscan2
- RAB34 | c.684G>A p.S228= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs750532684, COSV56389116; called by muse, mutect2, varscan2
- REC8 | c.387A>G p.L129= | Silent (SNP) | VAF 65/151 reads (43%) | catalogued as COSV100269076; called by muse, mutect2, varscan2
- RNF145 | c.1878C>T p.S626= (on ENST00000424310 / NM_001199383.2; = p.S654= on NM_144726.2) | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV99193585; called by muse, mutect2, varscan2
- RYR2 | c.10845G>T p.R3615= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100770817, COSV63657328; called by muse, mutect2, varscan2
- SEC16A | c.2607A>T p.A869= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99258750; called by muse, mutect2, varscan2
- SEMA4C | c.2355T>C p.N785= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV100561027; called by muse, mutect2, varscan2
- SHISA2 | c.468G>C p.G156= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100096318, COSV100096446; called by muse, mutect2, varscan2
- SI | c.3876C>T p.Y1292= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV100015826; called by muse, mutect2, varscan2
- SLC6A17 | c.249C>A p.I83= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100521353; called by muse, mutect2, varscan2
- SNTG2 | c.510G>T p.G170= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV57997205; called by muse, mutect2, varscan2
- SOCS2 | c.168T>C p.N56= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100500061; called by muse, mutect2, varscan2
- SORCS1 | c.441G>T p.P147= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV53864069, COSV53896753, COSV99547254; called by muse, mutect2, varscan2
- SPATA31E1 | c.876G>A p.V292= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV57796020; called by muse, mutect2, varscan2
- TRIM25 | c.489G>C p.L163= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV100381012; called by muse, mutect2, varscan2
- TRPM2 | c.2673G>T p.T891= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV100308913; called by muse, mutect2, varscan2
- TTN | c.95451T>C p.I31817= (on ENST00000591111; = p.I24393= on NM_003319.4) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1273247070, COSV100616672; called by muse, mutect2, varscan2
- VCPIP1 | c.2733A>G p.A911= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs201986090, COSV100125654; called by muse, mutect2, varscan2
- XIRP2 | c.354G>A p.Q118= (on ENST00000628543; = p.Q293= on NM_152381.6) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99743679; called by muse, mutect2, varscan2
- ZNF536 | c.2178C>A p.G726= | Silent (SNP) | VAF 311/440 reads (71%) | catalogued as COSV100835317, COSV62831659; called by muse, mutect2, varscan2
- ZP4 | c.1281T>A p.P427= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100850695; called by muse, mutect2, varscan2
- ZP4 | c.1029G>T p.R343= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100850696, COSV100850718, COSV63912386; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849751 G>T | 5'Flank (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1500A>T | 3'UTR (SNP) | VAF 34/101 reads (34%) | catalogued as COSV100354605; called by muse, mutect2, varscan2
- CPLANE1 | c.*4983dup | 3'UTR (INS) | VAF 48/241 reads (20%) | called by mutect2, pindel, varscan2
- LINC02870 | n.389C>G | RNA (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- LPAL2 | n.219C>T | RNA (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- MIR100 | n.62T>C | RNA (SNP) | VAF 14/60 reads (23%) | catalogued as rs749039221; called by muse, mutect2, varscan2
- MIR518E | n.23G>A | RNA (SNP) | VAF 31/127 reads (24%) | catalogued as rs1251153957; called by muse, mutect2, varscan2
- MORF4 | n.440G>C | RNA (SNP) | VAF 38/135 reads (28%) | catalogued as rs1346719210; called by muse, mutect2, varscan2
- PIK3C2B | c.934-1479G>T | Intron (SNP) | VAF 35/144 reads (24%) | catalogued as rs1342726929; called by muse, mutect2, varscan2
- STAG3L4 | n.677G>T | RNA (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- ZNF208 | c.*483A>C | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
